Somatic mutation profile of tumor specimen MMRF_2638_1_BM_CD138pos (aliquot MMRF_2638_1_BM_CD138pos_T1_KHS5U_L13320) from MMRF case MMRF_2638, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.9 years (19,686 days).
Specimen MMRF_2638_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65aaf655-6741-4711-b5dc-fe000b270ec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2638_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2638_1_PB_WBC_C3_KHS5U_L13321; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23f8c2b2-79d5-43c7-acc9-600592f943de

The open-access MAF lists 59 somatic variants for this specimen: 33 protein-altering or splice-affecting, 4 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 10, Silent 4, Intron 4, 5'UTR 3, 5'Flank 2, 3'Flank 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.131C>T p.A44V (on ENST00000377970; = p.A59V on NM_002467.6) | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775522201, COSV52367462, COSV99422212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 52/116 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTG1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs375159565; called by muse, mutect2, varscan2
- BCL7A | c.17T>A p.V6D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV55849466; called by muse, mutect2, varscan2
- CCND1 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV57120181, COSV57121338; called by muse, varscan2
- CHD2 | c.1225A>G p.N409D | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.061); catalogued as rs531251618; called by muse, mutect2, varscan2
- COBLL1 | c.832T>G p.F278V (on ENST00000392717; = p.F240V on NM_014900.5) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs35945844, COSV52063695, COSV52074221; called by muse, mutect2, varscan2
- FAM155A | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 100/189 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV65555434; called by muse, mutect2, varscan2
- IGHV2-70 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- IGLV2-11 | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.166); catalogued as rs761340679; called by muse, mutect2
- IGLV3-1 | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 74/106 reads (70%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs544582083; called by muse, varscan2
- KLHL40 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs1310855261; called by muse, mutect2, varscan2
- PRKD2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52189638; called by muse, mutect2, varscan2
- PTPRT | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); catalogued as COSV61986148, COSV61998479; called by muse, mutect2, varscan2
- RBP3 | c.2957G>A p.G986E | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1555211580; called by muse, mutect2, varscan2
- SCAF1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 125/298 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs1399443436, COSV62183423; called by muse, mutect2, varscan2
- SLC1A5 | c.1025C>G p.T342R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs778634582, COSV69467157; called by muse, mutect2, varscan2
- SLC28A1 | c.1294C>A p.L432M | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs200140490, COSV99723519; called by muse, mutect2, varscan2
- TAF2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs776974444, COSV100978707; called by muse, mutect2, varscan2
- TJAP1 | c.716C>T p.P239L (on ENST00000372445 / NM_001146016.1; = p.P229L on NM_080604.3) | Missense Mutation (SNP) | VAF 134/380 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs577012593; called by muse, mutect2, varscan2
- ZEB1 | c.506T>A p.L169* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | catalogued as COSV100314862; called by muse, mutect2
- ZNF804A | c.2392C>A p.P798T | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100168396, COSV99043259; called by muse, mutect2, varscan2
- ZNF831 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100925897; called by muse, mutect2, varscan2
- ACTN3 | c.2032C>G p.L678V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FBXO27 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGHV2-70 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPCAT2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OCM2 | c.212T>A p.F71Y | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH15 | c.5719T>G p.Y1907D | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PHF3 | c.6107A>G p.K2036R | Missense Mutation (SNP) | VAF 15/486 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2
- SGCZ | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS9D1 | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZNF462 | c.1741C>G p.Q581E | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOA5 | c.456C>T p.R152= | Silent (SNP) | VAF 98/222 reads (44%) | catalogued as COSV99911107; called by muse, mutect2, varscan2
- DLC1 | c.1227A>G p.T409= | Silent (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- KCNG1 | c.396C>T p.R132= | Silent (SNP) | VAF 68/186 reads (37%) | catalogued as rs763218689, COSV65370323; called by muse, mutect2, varscan2
- LRP1B | c.6072T>A p.A2024= | Silent (SNP) | VAF 11/277 reads (4%) | called by muse, mutect2
- C1orf226 | c.*264C>T | 3'UTR (SNP) | VAF 44/137 reads (32%) | called by muse, mutect2
- CPE | c.307+1894A>G | Intron (SNP) | VAF 47/91 reads (52%) | called by mutect2, varscan2
- DENND1B | c.-2C>T | 5'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- ERBB4 | c.*7129T>A | 3'UTR (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- FBXO3 | c.1239+440T>C | Intron (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- LHX1 | chr17:36937142 G>A | 5'Flank (SNP) | VAF 13/229 reads (6%) | called by muse, mutect2
- LILRB4 | c.*242G>A | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- LINC00470 | n.1361-2565G>A | Intron (SNP) | VAF 51/128 reads (40%) | called by muse, mutect2, varscan2
- LINC01591 | n.195T>G | RNA (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- LINC02871 | chr20:11029423 A>C | 3'Flank (SNP) | VAF 69/153 reads (45%) | called by muse, mutect2, varscan2
- MAP3K20 | c.988-4171C>T | Intron (SNP) | VAF 9/16 reads (56%) | catalogued as rs1484653793; called by muse, mutect2, varscan2
- MXRA8 | chr1:1358694 G>A | 5'Flank (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- NOS1 | c.-280C>T | 5'UTR (SNP) | VAF 38/117 reads (32%) | catalogued as rs1451746303; called by muse, mutect2, varscan2
- PTPN3 | c.*528G>C | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- RAD51AP1 | c.*421G>A | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- RNPS1 | chr16:2253354 C>A | 3'Flank (SNP) | VAF 133/303 reads (44%) | called by muse, mutect2, varscan2
- SENP5 | c.*2983C>G | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- SRSF9 | c.-15C>T | 5'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- TEAD1 | c.*147A>C | 3'UTR (SNP) | VAF 62/201 reads (31%) | called by muse, mutect2, varscan2
- WNT5A | c.*3963C>T | 3'UTR (SNP) | VAF 9/21 reads (43%) | catalogued as rs1029568154; called by muse, mutect2, varscan2
- ZCWPW2 | c.*391T>C | 3'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- ZNF462 | c.*1139G>A | 3'UTR (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
